Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4776, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4776-01A (Primary Tumor).

[page 1 of 2]
.....

Clinical Diagnosis & History:

Patient with left renal mass.

Specimens Submitted:

1: Kidney, left, partial nephrectomy

DIAGNOSIS:

1. Kidney, left, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 2.7 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

N/A

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

.....

[page 2 of 2]
Gross Description:

1). The specimen is received fresh labeled, "Left renal mass – partial nephrectomy", and consists of a portion of kidney parenchyma measuring 4.2 x 3.4 x 2.8 cm, with attached fat measuring 7.5 x 6 x 1.2 cm. The outer surface of the fat is inked blue. The resected margin of the kidney is inked black. Cut section reveals an encapsulated partially cystic hemorrhagic orange tumor nodule measuring 2.7 x 2.6 x 2.4 cm. The tumor does not grossly extend through the renal capsule or into the perinephric fat. It is located 0.2 cm from the resected margin. A representative section of the tumor is given to [REDACTED]. Representative sections are submitted.

Summary of sections:

TF – tumor with fat

TM – tumor with resected margin

RS-representative sections of normal kidney parenchyma

Summary of Sections:

Part 1: Kidney, left, partial nephrectomy

Block	Sect. Site	PCs
1	rs	1
2	tf	2
3	tm	3

Source: NCI Genomic Data Commons file 6858b530-2a22-4c0f-9b45-6db6775b2329 (TCGA-BP-4776.A96540D9-ED3E-4AEF-8E04-1E6E380339D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).